Surgical pathology report (de-identified scan), TCGA case TCGA-61-2002, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-61-2002-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: PELVIC TUMOR NODULE, EXCISION –

- A. POORLY DIFFERENTIATED CARCINOMA.
- B. TUMOR MEASURES UP TO APPROXIMATELY 1 CM IN GREATEST DIMENSION.

PART 2: LEFT ADNEXA, SALPINGO-OOPHORECTOMY –

- A. POORLY DIFFERENTIATED PAPILLARY SEROUS ADENOCARCINOMA (see comment).
- B. TUMOR MEASURES 5.4 CM IN GREATEST DIMENSION.
- C. LYMPHOVASCULAR INVASION IS PRESENT.
- D. TUMOR INVOLVES BOTH THE SEROSAL AND LUMINAL ASPECTS OF THE FALLOPIAN TUBE.
- E. RESIDUAL OVARIAN TISSUE IS NOT IDENTIFIED.

PART 3: RIGHT ADNEXA, SALPINGO-OOPHORECTOMY –

- A. OVARY WITH INVOLVEMENT BY MULTIPLE NODULES OF POORLY DIFFERENTIATED CARCINOMA MEASURING UP TO APPROXIMATELY 1.0 CM IN GREATEST DIMENSION.
- B. FALLOPIAN TUBE WITH ADHESIONS, NEGATIVE FOR NEOPLASM.

PART 4: PELVIC TUMOR, EXCISION –

SEGMENTS OF FIBROADIPOSE TISSUE WITH POORLY DIFFERENTIATED CARCINOMA MEASURING UP TO APPROXIMATELY 0.5 CM IN GREATEST DIMENSION.

PART 5: OMENTUM, OMENTECTOMY –

POORLY DIFFERENTIATED ADENOCARCINOMA, MEASURING APPROXIMATELY 1.5 CM IN GREATEST DIMENSION.

PART 6: LEFT PERIAORTIC LYMPH NODES, BIOPSY –

- A. ONE LYMPH NODE WITH METASTATIC ADENOCARCINOMA (1/1).
- B. METASTASIS MEASURES APPROXIMATELY 2.2 CM IN GREATEST DIMENSION.
- C. EXTRACAPSULAR EXTENSION IS PRESENT (APPROXIMATELY 7 MM.).

PART 7: LEFT PELVIC LYMPH NODES, BIOPSY –

- A. ONE LYMPH NODE, NEGATIVE FOR TUMOR (0/1).
- B. MINUTE SUBCAPSULAR FRAGMENT OF ATYPICAL CELLS.

PART 8: INTRAABDOMINAL CLOT, EXCISION –

ORGANIZING HEMORRHAGE.

PART 9: RIGHT PERIAORTIC LYMPH NODES, BIOPSY –

ONE LYMPH NODE, NEGATIVE FOR NEOPLASM (0/1).

PART 10: AORTIC CAVAL LYMPH NODE, BIOPSY –

ONE LYMPH NODE, NEGATIVE FOR NEOPLASM (0/1).

PART 11: APPENDIX AND APPENDICEAL STUMP, APPENDECTOMY –

APPENDIX WITH FIBRINOUS ADHESIONS, NEGATIVE FOR NEOPLASM.

PART 12: BOWEL TUMOR, EXCISION –

SEGMENTS OF POORLY DIFFERENTIATED CARCINOMA MEASURING UP TO PROXIMATELY 0.6 CM IN GREATEST DIMENSION.

PART 13: MESENTERIC LYMPH NODE, BIOPSY –

ONE LYMPH NODE, NEGATIVE FOR NEOPLASM (0/1).

PART 14: RIGHT UPPER QUADRANT MASS, EXCISION –

- A. SMALL FOCI OF POORLY DIFFERENTIATED CARCINOMA MEASURING UP TO APPROXIMATELY 1.5 CM IN GREATEST DIMENSION.
- B. ADHESIONS, FAT NECROSIS, AND GRANULATION TISSUE.

Source: NCI Genomic Data Commons file 6c63d490-f312-473a-af0d-c8ccc8c5d7bb (TCGA-61-2002.8030B8AA-9686-45B3-BF39-1889A6B8B36F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).